Gene-level copy-number profile of tumor specimen TCGA-AA-A017-01A from TCGA case TCGA-AA-A017, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 57.6 years (21,032 days).
Specimen TCGA-AA-A017-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6131b68a-3c1c-466a-9c0b-4cd4330cd438.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-A017-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/53b561fc-f6f7-4a32-bc44-c55d031dae46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 524; copy number 1: 7,508; copy number 2: 45,552; copy number 3: 4,302; copy number 4: 750; copy number 5: 671; copy number 6: 919; copy number 7: 3; copy number 10: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AA-A017-01A-01D-A008-01): tumor purity 0.58, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:99,512,501–99,513,576, 1 gene: AL110504.1.
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,639 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:35,768,652–36,490,441, 9 genes, copy number 5 (within-gene range 4–5): DCLK1, SOHLH2, CCDC169-SOHLH2, CCDC169, RNU6-71P, SPART, SPART-AS1, CCNA1, H2ACP1.
- chr13:38,965,925–39,223,238, 5 genes, copy number 5: STOML3, PROSER1, NHLRC3, AL354809.1, NXT1P1.
- chr13:43,158,631–73,995,056, 390 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 1 gene, copy number 5 (within-gene range 4–5): GPC6.
- chr13:93,394,977–98,752,672, 71 genes, copy number 5 (broad region; genes not listed).
- chr13:99,835,813–102,402,457, 33 genes, copy number 5 (within-gene range 4–5): AL137139.3, AL137139.2, ZIC5, AL355338.1, ZIC2, LINC00554, NDUFA12P1, PCCA-DT, ASNSP3, PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6, NALCN-AS1, ARF4P3, LINC00411, NALCN, ITGBL1, FGF14, AL160153.1, RNU1-24P, HMGB3P7, MIR2681, LIPT1P1, RNY1P2, MIR4705.
- chr13:104,814,327–114,337,626, 162 genes, copy number 5 (broad region; genes not listed).
- chr20:24,931,840–64,313,132, 968 genes, copy number 6–10 (within-gene range 4–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,506. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
